Gene-level copy-number profile of tumor specimen TCGA-V4-A9EO-01A from TCGA case TCGA-V4-A9EO, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Ciliary body; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 74.4 years (27,190 days).
Specimen TCGA-V4-A9EO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.5b0ab857-77d6-48d0-9d37-63f8aa4c92e0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V4-A9EO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0f745119-18ab-4f29-9f5f-77a9653b7c37

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,381; copy number 2: 6,050; copy number 3: 23,871; copy number 4: 23,856; copy number 5: 2,683; copy number 6: 979.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V4-A9EO-01A-12D-A39V-01): tumor purity 0.98, ploidy 3.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
